Gene-level copy-number profile of tumor specimen TCGA-DX-AB2V-01A from TCGA case TCGA-DX-AB2V, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB2V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.096f354f-7479-4c65-a73e-18dbb2d631da.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/36339cc8-fb3a-462a-b7f8-b51ae06ae596

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,020; copy number 2: 9,231; copy number 3: 19,461; copy number 4: 6,632; copy number 5: 11,433; copy number 6: 5,915; copy number 7: 1,917; copy number 8: 1,457; copy number 9: 483; copy number 10: 235; copy number 11: 23; copy number 13: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2V-01A-11D-A416-01): tumor purity 0.78, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,124 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,059,232–157,237,136, 8 genes, copy number 8: SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1, AL357143.2, AL138900.1.
- chr3:85,992,183–91,513,775, 42 genes, copy number 8: CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr5:3,357,264–69,160,939, 900 genes, copy number 7–10 (broad region; genes not listed).
- chr5:88,189,633–128,189,677, 495 genes, copy number 7 (broad region; genes not listed).
- chr5:165,782,805–166,926,370, 6 genes, copy number 7: AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947.
- chr7:63,011,463–77,995,171, 409 genes, copy number 7 (broad region; genes not listed).
- chr7:78,134,079–78,487,028, 5 genes, copy number 7: AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1.
- chr7:88,205,115–89,754,726, 17 genes, copy number 8: SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P.
- chr7:91,264,433–92,590,393, 27 genes, copy number 7: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B.
- chr7:92,638,198–92,667,083, 2 genes, copy number 7 (within-gene range 6–7): AC000065.2, AC000065.1.
- chr7:93,777,839–96,709,891, 50 genes, copy number 7: AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1.
- chr8:38,030,534–43,674,591, 145 genes, copy number 10 (broad region; genes not listed).
- chr12:70,468,080–70,920,738, 5 genes, copy number 8 (within-gene range 6–8): AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:84,147,304–84,449,878, 4 genes, copy number 10: AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr12:96,194,375–96,979,629, 12 genes, copy number 8–13 (within-gene range 6–13): ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA.
- chr12:111,642,146–113,789,807, 59 genes, copy number 7: BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4.
- chr12:114,657,949–115,080,153, 9 genes, copy number 8: Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1.
- chr12:115,582,061–115,639,734, 1 gene, copy number 9 (within-gene range 5–9): AC009803.1.
- chr12:115,717,725–116,428,318, 14 genes, copy number 9: RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1, MIR4472-2.
- chr12:120,640,552–121,059,670, 20 genes, copy number 7 (within-gene range 5–7): CABP1, MLEC, AC069234.2, AC069234.5, AC069234.4, UNC119B, AC069234.3, MIR4700, ACADS, AC069234.1, SPPL3, ARF1P2, AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, OASL2P.
- chr12:123,973,241–124,316,024, 1 gene, copy number 8 (within-gene range 5–8): RFLNA.
- chr12:124,206,228–125,662,377, 32 genes, copy number 8 (within-gene range 5–8): AC026358.1, NCOR2, MIR6880, AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19, DHX37, BRI3BP, THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.5, AC122688.4, TMEM132B, AC093028.1.
- chr12:125,858,132–126,043,485, 5 genes, copy number 9 (within-gene range 5–9): AC005252.4, AC005252.3, AC005252.1, LINC00939, LINC02826.
- chr12:127,130,005–127,207,706, 5 genes, copy number 10: AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6.
- chr12:128,116,730–128,244,573, 3 genes, copy number 9: LINC02368, AC061709.2, AC061709.1.
- chr12:131,347,470–132,829,078, 71 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:132,825,701–132,867,958, 3 genes, copy number 7: RPS11P5, RNU6-327P, AC127070.4.
- chr14:18,333,726–48,819,593, 776 genes, copy number 8–9 (broad region; genes not listed).
- chr14:51,304,108–54,902,826, 68 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:64,914,485–65,061,803, 1 gene, copy number 11 (within-gene range 4–11): CHURC1-FNTB.
- chr14:64,986,895–66,004,523, 22 genes, copy number 11 (within-gene range 6–11): FNTB, AL139022.2, MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708, FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2, NCOA4P1, FTH1P13, AL391261.1, AL391261.2.
- chr14:67,819,779–68,730,218, 1 gene, copy number 9 (within-gene range 6–9): RAD51B.
- chr14:68,149,617–68,979,440, 16 genes, copy number 9 (within-gene range 6–9): RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3.
- chr14:71,932,429–72,566,530, 1 gene, copy number 7 (within-gene range 6–7): RGS6.
- chr14:72,515,407–74,876,154, 86 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr14:92,513,781–94,390,693, 41 genes, copy number 7: RIN3, LGMN, GOLGA5, LINC02833, LINC02287, CHGA, ITPK1, ITPK1-AS1, CYB5AP3, MOAP1, TMEM251, AL110118.1, GON7, UBR7, AL132838.1, BTBD7, AL132838.2, UNC79, AL122023.1, COX8C, Y_RNA, RNU6-1258P, AL157858.2, PRIMA1, AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2, PPP4R4, SERPINA10, SERPINA6, SERPINA2, SERPINA1.
- chr14:96,797,382–106,875,071, 544 genes, copy number 8–10 (broad region; genes not listed).
- chr17:63,430,468–65,458,408, 89 genes, copy number 7 (broad region; genes not listed).
- chr19:43,153,279–45,038,198, 104 genes, copy number 7 (broad region; genes not listed).
- chr20:13,849,247–16,573,448, 23 genes, copy number 7 (within-gene range 5–7): SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B.

Autosomal genes at a single copy (total copy number 1): 3,020. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
